Somatic mutation profile of tumor specimen TCGA-91-7771-01A (aliquot TCGA-91-7771-01A-11D-2167-08) from TCGA case TCGA-91-7771, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.8 years (22,926 days).
Specimen TCGA-91-7771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80e03a98-f4e8-42a8-9b6e-5b502222690b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-7771-10A (Blood Derived Normal), aliquot TCGA-91-7771-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32b00d18-e064-44d7-ada0-78ff1a8160b7

The open-access MAF lists 201 somatic variants for this specimen: 152 protein-altering or splice-affecting, 45 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 45, Nonsense Mutation 6, Frame Shift Del 6, Intron 2, 3'UTR 1, Splice Site 1, Splice Region 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACKR3 | c.329G>C p.W110S | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56020291; called by muse, mutect2
- ACY1 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.838); catalogued as COSV53685481; called by muse, mutect2
- ADAMTS13 | c.2620A>G p.T874A | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as rs1554792342, COSV63019825; called by muse, mutect2, varscan2
- ADAMTS17 | c.1987A>G p.T663A | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs76569625, COSV51471928; called by muse, mutect2, varscan2
- ADAMTS20 | c.1886A>C p.H629P | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV67125594; called by muse, mutect2, varscan2
- ADCYAP1 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.306); catalogued as rs8192594, COSV52485636, COSV52486264; called by muse, mutect2
- AGBL2 | c.2701T>C p.Y901H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54089739; called by muse, mutect2, varscan2
- AGMAT | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101011778; called by muse, mutect2
- AKAP6 | c.2207A>T p.Y736F | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55203183; called by muse, mutect2
- ALDH6A1 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362472778, COSV63245678; called by muse, mutect2, varscan2
- ANKRD50 | c.3820G>C p.E1274Q | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV72384972; called by muse, mutect2, varscan2
- ANXA7 | c.650A>G p.N217S (on ENST00000372919 / NM_001320880.2; = p.N195S on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as rs369628555; called by muse, mutect2, varscan2
- ARPP21 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51791209; called by muse, mutect2, varscan2
- ASB10 | c.317G>T p.R106I (on ENST00000420175 / NM_001142459.2; = p.G91V on NM_080871.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV99318592; called by muse, mutect2
- ASXL3 | c.3818C>T p.T1273I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as rs769334860, COSV52455880; called by muse, mutect2, varscan2
- ATP6V1A | c.1489G>T p.G497* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV56360708; called by muse, mutect2, varscan2
- B3GAT2 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57768417; called by muse, mutect2
- B4GALNT3 | c.1346A>T p.N449I | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV56749260; called by muse, mutect2, varscan2
- BNC2 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV66140058; called by muse, mutect2, varscan2
- BRCA2 | c.6445A>G p.I2149V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs786202013, CD020560, CD044128, COSV66447486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTAF1 | c.3598G>C p.D1200H | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56429248; called by muse, mutect2, varscan2
- C18orf54 | c.256T>A p.C86S | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55617113; called by muse, mutect2
- C3 | c.4445A>G p.Y1482C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55567890; called by muse, mutect2, varscan2
- CAMK4 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV56660930; called by muse, mutect2
- CBLB | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs1159337338, COSV51420552, COSV51425204; called by muse, mutect2
- CBX2 | c.1489C>A p.R497S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53968321; called by muse, mutect2, varscan2
- CD1A | c.326-1G>C p.X109_splice | Splice Site (SNP) | VAF 7/138 reads (5%) | catalogued as COSV56860114, COSV99192433; called by muse, mutect2
- CKAP5 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV56363419; called by muse, mutect2, varscan2
- CNTNAP2 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62140241, COSV62213628; called by muse, mutect2, varscan2
- CR1 | c.5433G>A p.M1811I | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as COSV65455397; called by muse, mutect2, varscan2
- CRLF2 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV67493373, COSV67494256; called by muse, mutect2
- CTSA | c.1374G>T p.M458I | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1568768160, COSV51940287; called by muse, mutect2
- CUBN | c.6360G>T p.W2120C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64706643; called by muse, mutect2, varscan2
- CUBN | c.2860C>A p.H954N | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.301); catalogued as rs766733151, COSV64706648; called by muse, mutect2
- DGKH | c.3530T>C p.I1177T | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV54926961; called by muse, mutect2, varscan2
- DKK2 | c.539G>C p.G180A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53393292; called by muse, mutect2
- DNAJB2 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV60675432; called by muse, mutect2
- DSCAML1 | c.3401C>T p.T1134M (on ENST00000321322; = p.T1074M on NM_020693.4) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs746275716, COSV58380179; called by muse, mutect2, varscan2
- ELAVL3 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV52950091; called by muse, mutect2, varscan2
- EPPK1 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.201); catalogued as rs370774174; called by muse, mutect2
- ERCC4 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100318693, COSV61310505; called by muse, mutect2, varscan2
- EYA1 | c.761C>A p.A254D | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as rs1281786069, COSV58156342; called by muse, mutect2
- FANCM | c.1593G>T p.Q531H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV57496776, COSV99951891; called by muse, varscan2
- FCHSD2 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV60806028; called by muse, mutect2, varscan2
- FOXQ1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV57258540; called by muse, mutect2
- GABRB3 | c.649C>A p.R217S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV54648717, COSV54671867; called by muse, varscan2
- GIGYF2 | c.600A>T p.E200D | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV101004406, COSV65245881; called by muse, mutect2, varscan2
- GLUL | c.474G>A p.Q158= | Splice Region (SNP) | VAF 27/130 reads (21%) | catalogued as COSV59381516; called by muse, mutect2, varscan2
- GMPR | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1240671486, COSV52471896; called by muse, mutect2, varscan2
- GOLGA4 | c.6362A>T p.D2121V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62708911; called by muse, mutect2, varscan2
- GPR174 | c.762C>G p.F254L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV52131311, COSV52131829; called by muse, mutect2, varscan2
- H2BC17 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV100377488, COSV58151845; called by muse, mutect2
- HCK | c.1566C>A p.Y522* | Nonsense Mutation (SNP) | VAF 3/31 reads (10%) | catalogued as COSV52940017; called by muse, mutect2
- HUWE1 | c.4912A>G p.I1638V | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53332917; called by muse, mutect2, varscan2
- IFNB1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 54/220 reads (25%) | catalogued as COSV66525062; called by muse, mutect2, varscan2
- IGF2 | c.473C>T p.P158L (on ENST00000434045 / NM_001127598.3; = p.P102L on NM_000612.6) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs369122420, COSV56096927; called by mutect2, varscan2
- IKBKB | c.2066C>G p.S689C | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.682); catalogued as COSV60595514, COSV60598152; called by muse, mutect2, varscan2
- IL2RA | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 4/99 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56919438; called by muse, mutect2
- ITGB6 | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1260682322, COSV51790380; called by muse, mutect2, varscan2
- ITPR2 | c.2602G>T p.A868S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67263834; called by muse, mutect2, varscan2
- KIAA1522 | c.2971C>T p.P991S (on ENST00000373480 / NM_001198972.2; = p.P1050S on NM_020888.3) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.738); catalogued as rs745962997, COSV53862050; called by muse, mutect2, varscan2
- KIR3DL1 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 49/348 reads (14%) | catalogued as COSV58487257, COSV58488353; called by muse, mutect2, varscan2
- LCE3E | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV64231483; called by muse, mutect2, varscan2
- LHFPL6 | c.203G>A p.C68Y | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV65443373; called by muse, mutect2, varscan2
- ME1 | c.730T>G p.F244V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63837277; called by muse, mutect2, varscan2
- MED7 | c.81A>T p.Q27H | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV53849650; called by muse, mutect2
- MGMT | c.118C>T p.R40C (on ENST00000306010; = p.R9C on NM_002412.5) | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.865); catalogued as rs141095230; called by muse, mutect2, varscan2
- MIA2 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs200876456, COSV54481706; called by muse, mutect2
- MUC5AC | c.170C>A p.A57E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); catalogued as COSV62253159; called by muse, mutect2, varscan2
- NCBP1 | c.2280G>T p.Q760H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV64304798; called by muse, mutect2, varscan2
- NCOA2 | c.1960C>G p.P654A | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.654); catalogued as COSV71763314; called by muse, mutect2, varscan2
- NIPSNAP2 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59050120, COSV59051280; called by muse, mutect2
- NKAIN2 | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.019); catalogued as COSV63641153, COSV63675065; called by muse, mutect2
- NLRP2 | c.725C>A p.A242E | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54751859, COSV54752546; called by muse, mutect2, varscan2
- NLRP2 | c.919del p.D307Tfs*16 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | catalogued as COSV54760793; called by mutect2, pindel, varscan2
- NMRK2 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV51454746; called by muse, mutect2
- NPPB | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs777621972, COSV64687232; called by muse, mutect2, varscan2
- NRP1 | c.1318G>C p.G440R | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55158906, COSV55159847; called by muse, mutect2, varscan2
- NUP210L | c.4156C>T p.Q1386* | Nonsense Mutation (SNP) | VAF 10/142 reads (7%) | catalogued as COSV99668032; called by muse, mutect2
- OR13C9 | c.290G>C p.C97S | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1177201466, COSV52240499, COSV52242164; called by muse, mutect2, varscan2
- OR2M2 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 26/340 reads (8%) | catalogued as COSV62897670, COSV62898419; called by muse, mutect2
- OR2M3 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 152/536 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV71758819; called by muse, mutect2, varscan2
- OR4A15 | c.818T>A p.L273Q | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV59033448, COSV59037691; called by muse, mutect2, varscan2
- OR4X2 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV56582002; called by muse, mutect2
- OR52A5 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as rs1327050689, COSV56614024; called by muse, mutect2, varscan2
- OR5I1 | c.776T>G p.F259C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56885191; called by muse, mutect2, varscan2
- PCDH15 | c.2809C>A p.P937T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1463920111, COSV57256730; called by muse, mutect2, varscan2
- PCDHA5 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.205); catalogued as rs781935410, COSV65348896, COSV65349945; called by muse, mutect2, varscan2
- PCDHGA1 | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as COSV65294653; called by muse, mutect2, varscan2
- PCLO | c.11223C>A p.S3741R | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV61612641; called by muse, mutect2, varscan2
- PLCB1 | c.2718A>C p.E906D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.425); catalogued as COSV62035959; called by muse, mutect2
- PLEKHA2 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66241964, COSV66242351; called by muse, mutect2
- PRDM9 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); catalogued as rs749429353, COSV57001708; called by muse, mutect2, varscan2
- PRKG1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV64792660; called by muse, mutect2, varscan2
- PRKG1 | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100908470; called by muse, mutect2, varscan2
- PRPF40B | c.1093C>A p.R365S (on ENST00000380281; = p.R359S on NM_012272.3) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.278); catalogued as COSV56057477, COSV99979846; called by muse, mutect2, varscan2
- PTCH1 | c.2947G>A p.D983N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV59461039; called by muse, mutect2, varscan2
- PTPN13 | c.5285C>G p.T1762S (on ENST00000411767 / NM_080683.3; = p.T1743S on NM_006264.3) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV57401459; called by muse, mutect2, varscan2
- PTPRN | c.734G>A p.S245N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.138); catalogued as COSV55345241; called by muse, mutect2, varscan2
- PYGO2 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63756542; called by muse, mutect2, varscan2
- QSOX2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1415493786, COSV62393235; called by muse, mutect2, varscan2
- RAB3IP | c.142G>A p.E48K (on ENST00000550536 / NM_175623.4; = p.E32K on NM_022456.5) | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.98); catalogued as COSV56081374; called by muse, mutect2
- RAB3IP | c.349G>A p.G117R (on ENST00000550536 / NM_175623.4; = p.G101R on NM_022456.5) | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV56081387; called by muse, mutect2
- RAI2 | c.87G>T p.M29I | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV58962631; called by muse, mutect2, varscan2
- RASGEF1A | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1375844367, COSV65666584; called by muse, mutect2
- RBMXL2 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs1565036049, COSV100182224, COSV60981497; called by muse, mutect2, varscan2
- RIF1 | c.3745G>C p.V1249L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV54611779; called by muse, mutect2, varscan2
- RLIM | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60324925; called by muse, mutect2, varscan2
- RPAP1 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as COSV58536946; called by muse, mutect2
- RPS6 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as rs1349311204, COSV59547415; called by muse, mutect2
- RTL3 | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58182912; called by muse, mutect2, varscan2
- SCN10A | c.3322C>A p.L1108M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.975); catalogued as COSV71860067; called by muse, mutect2, varscan2
- SCN1A | c.3380T>C p.L1127S (on ENST00000303395 / NM_001202435.3; = p.L1116S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as COSV57658540; called by muse, mutect2
- SGO1 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV55422615; called by muse, mutect2, varscan2
- SLC4A10 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV99763982; called by muse, mutect2, varscan2
- SLITRK3 | c.56T>A p.L19H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53845230; called by muse, mutect2, varscan2
- SMR3A | c.160C>G p.H54D | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV56949550; called by muse, mutect2, varscan2
- SNAP25 | c.212T>A p.M71K | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV54770070; called by muse, mutect2, varscan2
- STK11 | c.127del p.A43Pfs*8 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as CD991880; called by mutect2, pindel, varscan2
- STPG2 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.087); catalogued as rs772953505, COSV54783241, COSV54825855; called by muse, mutect2, varscan2
- TAB2 | c.925C>G p.H309D | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV53850831; called by muse, mutect2, varscan2
- TBC1D2 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs772793838, COSV59782246; called by muse, mutect2, varscan2
- THSD7B | c.862C>G p.H288D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as COSV55648622, COSV99754176; called by muse, mutect2, varscan2
- TMEM59 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568171641, COSV52372457; called by muse, mutect2, varscan2
- TMEM59L | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53241474; called by muse, mutect2, varscan2
- TTC33 | c.287A>T p.Y96F | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV61802236; called by muse, mutect2
- TTN | c.100900G>A p.E33634K (on ENST00000591111; = p.E26210K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | PolyPhen benign (0.297); catalogued as COSV59862021, COSV60301563; called by muse, mutect2
- TTN | c.66820C>A p.P22274T (on ENST00000591111; = p.P14850T on NM_003319.4) | Missense Mutation (SNP) | VAF 11/213 reads (5%) | PolyPhen benign (0.23); catalogued as COSV59862090; called by muse, mutect2
- TTN | c.47027C>A p.P15676H (on ENST00000591111; = p.P8252H on NM_003319.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | PolyPhen possibly damaging (0.518); catalogued as COSV59862125; called by muse, mutect2, varscan2
- TTN | c.30890C>A p.A10297D (on ENST00000591111; = p.A9370D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/180 reads (10%) | PolyPhen benign (0.076); catalogued as rs376754004; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.14334G>T p.Q4778H (on ENST00000591111; = p.Q3851H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | PolyPhen benign (0.003); catalogued as COSV59862164; called by muse, mutect2, varscan2
- TYR | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54469089, COSV99633279; called by muse, mutect2
- UBQLN1 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV57406596; called by muse, mutect2, varscan2
- UCHL1 | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs891105173, COSV52650819; called by muse, mutect2, varscan2
- UNCX | c.549C>A p.S183R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60332711; called by muse, mutect2, varscan2
- USP1 | c.503A>G p.E168G | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV60573472; called by muse, mutect2
- YTHDF2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65722518; called by muse, mutect2, varscan2
- ZFY | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.719); catalogued as COSV50082947; called by muse, mutect2, varscan2
- ZNF208 | c.1945G>T p.V649F | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV68099477, COSV68100873; called by muse, varscan2
- ZNF317 | c.1139A>G p.H380R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56108138; called by muse, mutect2, varscan2
- ZNF512B | c.2333C>A p.A778D | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53865281; called by muse, mutect2
- ZNF829 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV61740293; called by muse, mutect2, varscan2
- ABCC12 | c.983T>C p.I328T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by mutect2, varscan2
- AREG | c.339C>G p.N113K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2
- CRYBG2 | c.1202C>A p.A401D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- FAM228A | c.580_582del p.L194del | In Frame Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel
- KDM4D | c.627del p.T211Lfs*54 | Frame Shift Del (DEL) | VAF 19/112 reads (17%) | called by mutect2, pindel, varscan2
- MRC1 | c.3099G>T p.W1033C | Missense Mutation (SNP) | VAF 18/365 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- PPP1R26 | c.3324del p.L1109Cfs*45 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | called by mutect2, pindel
- TBXT | c.646del p.A216Lfs*14 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- UGT3A1 | c.1419del p.Y474Mfs*47 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- WASHC2A | c.3382G>T p.D1128Y | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ADH1A | c.213C>A p.A71= | Silent (SNP) | VAF 41/239 reads (17%) | catalogued as COSV52924151, COSV52925050; called by muse, mutect2, varscan2
- ARHGEF25 | c.882G>T p.R294= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV54084052; called by muse, mutect2, varscan2
- ATP9A | c.2358A>T p.G786= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV58762344; called by muse, mutect2
- CACNA1D | c.4185G>T p.A1395= (on ENST00000350061 / NM_001128840.3; = p.A1415= on NM_000720.4) | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV55436061; called by muse, mutect2, varscan2
- CD81 | c.42C>T p.L14= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV55132011; called by muse, mutect2
- CDH7 | c.1467C>T p.T489= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs147764044; called by muse, mutect2, varscan2
- CDS1 | c.1195A>C p.R399= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as COSV55686351; called by muse, mutect2, varscan2
- CLDN7 | c.603C>T p.Y201= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV63038715; called by muse, mutect2, varscan2
- D2HGDH | c.1101G>C p.V367= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV58318813; called by muse, mutect2, varscan2
- DAB1 | c.1011C>A p.G337= (on ENST00000371231; = p.G304= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100976322, COSV64691347; called by muse, mutect2
- DISP2 | c.2859G>T p.L953= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV99139979; called by muse, mutect2, varscan2
- ECM2 | c.1524C>T p.T508= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV60738853, COSV60739206; called by muse, mutect2, varscan2
- ERP29 | c.390C>T p.V130= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV55673156; called by muse, varscan2
- FAM155A | c.1083T>C p.C361= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV65547224; called by muse, mutect2, varscan2
- FST | c.438A>G p.L146= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV56814784; called by muse, mutect2, varscan2
- FZD4 | c.1275A>C p.T425= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV72294141; called by muse, mutect2, varscan2
- GABRB3 | c.627G>T p.P209= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV54648742; called by muse, varscan2
- GRXCR1 | c.114G>T p.P38= | Silent (SNP) | VAF 21/244 reads (9%) | catalogued as COSV67669715, COSV67671017; called by muse, mutect2
- IL23A | c.390C>T p.G130= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV57335787; called by muse, mutect2, varscan2
- IP6K1 | c.1038T>A p.A346= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV57694741; called by muse, mutect2, varscan2
- KLHL28 | c.111C>T p.I37= | Silent (SNP) | VAF 19/155 reads (12%) | catalogued as rs1003755160, COSV61887235; called by muse, mutect2, varscan2
- LCN1 | c.9C>G p.P3= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1408885740, COSV55017011; called by muse, mutect2, varscan2
- MAST4 | c.7779C>T p.R2593= (on ENST00000403625 / NM_001164664.2; = p.R2404= on NM_015183.3) | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV55113978; called by muse, mutect2
- MEOX2 | c.909C>T p.H303= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV56287134; called by muse, mutect2, varscan2
- MYB | c.933A>T p.G311= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV57195705; called by muse, mutect2
- NCAPG2 | c.2286C>T p.V762= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV51984083, COSV51993144; called by muse, mutect2, varscan2
- NLRP10 | c.1734T>A p.G578= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV60778418; called by muse, mutect2, varscan2
- NMBR | c.561C>A p.I187= | Silent (SNP) | VAF 9/208 reads (4%) | catalogued as COSV57800296; called by muse, mutect2
- OR2M5 | c.42C>G p.L14= | Silent (SNP) | VAF 44/403 reads (11%) | catalogued as COSV63545538; called by muse, mutect2, varscan2
- OR6K2 | c.108T>A p.A36= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as COSV62742997; called by muse, mutect2, varscan2
- PIGW | c.1182T>A p.I394= | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- PROM1 | c.651C>A p.A217= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV71699067; called by muse, mutect2, varscan2
- PROX1 | c.105T>C p.A35= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV54775397; called by muse, mutect2
- RBM5 | c.1242G>A p.Q414= | Silent (SNP) | VAF 63/216 reads (29%) | catalogued as COSV61736353; called by muse, mutect2, varscan2
- STAB2 | c.4344C>A p.T1448= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as COSV101185949; called by muse, mutect2
- STXBP5 | c.448C>T p.L150= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV51647237; called by muse, mutect2
- SYCE2 | c.187C>T p.L63= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV53365273, COSV53365311; called by muse, mutect2
- TDRD6 | c.1875C>A p.L625= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100287574; called by muse, mutect2, varscan2
- TICRR | c.4554T>A p.P1518= | Silent (SNP) | VAF 65/123 reads (53%) | catalogued as COSV51537297; called by muse, mutect2, varscan2
- TMEM139 | c.24G>C p.G8= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV60081270; called by muse, mutect2, varscan2
- TTN | c.93837G>A p.R31279= (on ENST00000591111; = p.R23855= on NM_003319.4) | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs766955284, COSV59862053; called by muse, mutect2, varscan2
- USH2A | c.3204T>G p.S1068= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV56321802; called by muse, mutect2
- VWF | c.6151A>C p.R2051= | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as COSV54610325; called by muse, mutect2, varscan2
- WARS2 | c.660A>T p.L220= | Silent (SNP) | VAF 48/226 reads (21%) | catalogued as COSV52475345; called by muse, mutect2, varscan2
- XDH | c.3108G>T p.G1036= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs766071282, COSV101052224, COSV65146649; called by muse, mutect2, varscan2
- FMN1 | c.2044-2064G>T | Intron (SNP) | VAF 12/119 reads (10%) | catalogued as COSV57916490; called by muse, mutect2, varscan2
- MIR509-3 | n.63T>A | RNA (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2, varscan2
- MTMR11 | c.*239C>T | 3'UTR (SNP) | VAF 10/92 reads (11%) | catalogued as rs1463899360, COSV99641153; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-23941T>C | Intron (SNP) | VAF 38/212 reads (18%) | catalogued as COSV67439744; called by muse, mutect2, varscan2
